CCDI case PBBSJY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1d5d22e5-ac5e-412a-9e78-098444d0bfa5

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.6 years (568 days).

Biospecimens (3 samples)
- Sample 0DFRTT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFRTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFRTV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
